Somatic mutation profile of tumor specimen MMRF_2595_1_BM_CD138pos (aliquot MMRF_2595_1_BM_CD138pos_T1_KHS5U_L12854) from MMRF case MMRF_2595, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,039 days).
Specimen MMRF_2595_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dc9ff28-67f8-4def-8d91-739a73d1b1ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2595_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2595_1_PB_Whole_C3_KHS5U_L12855; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7127b704-5206-47e6-acc0-c54c518ada28

The open-access MAF lists 239 somatic variants for this specimen: 100 protein-altering or splice-affecting, 25 silent, 114 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, 3'UTR 72, Silent 25, Intron 21, 5'UTR 9, RNA 5, 5'Flank 4, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 216/525 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROM1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 150/489 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs137853006, CM083044, COSV101477144, COSV71699500; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3610G>A p.V1204M | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs772566323, COSV62322115; called by muse, mutect2, varscan2
- ACTR3B | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV55451900; called by muse, mutect2, varscan2
- ADGRA2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs267601911; called by muse, mutect2, varscan2
- AKR1B10 | c.742-6G>A | Splice Region (SNP) | VAF 99/379 reads (26%) | catalogued as rs187796884; called by muse, mutect2, varscan2
- ALDH9A1 | c.4T>C p.F2L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1433810489; called by muse, mutect2, varscan2
- ANKRD34C | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs750628624, COSV101409601; called by muse, mutect2
- ARFGEF3 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1178661944; called by muse, mutect2, varscan2
- ARID1A | c.3867-1G>A p.X1289_splice | Splice Site (SNP) | VAF 110/234 reads (47%) | catalogued as COSV61372008; called by muse, mutect2, varscan2
- ATP2B2 | c.1729C>T p.R577C (on ENST00000352432; = p.R543C on NM_001683.5) | Missense Mutation (SNP) | VAF 128/187 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1360871132, COSV59507425; called by muse, mutect2, varscan2
- AXL | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs962997099, COSV56564670; called by muse, mutect2, varscan2
- FAXC | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs199850440, COSV67602067; called by muse, mutect2, varscan2
- FRMPD1 | c.4453G>C p.E1485Q | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs760505793, COSV66703113, COSV66703616; called by muse, mutect2, varscan2
- IGHJ1 | c.8A>T p.Y3F | Missense Mutation (SNP) | VAF 42/43 reads (98%) | catalogued as rs782279844; called by muse, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, varscan2
- IGSF3 | c.2305G>A p.V769I (on ENST00000369486 / NM_001007237.3; = p.V789I on NM_001542.4) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as rs200477999, COSV59589538; called by muse, mutect2, varscan2
- INTS11 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.378); catalogued as rs1246401538, COSV60087563; called by muse, mutect2, varscan2
- KDM5B | c.4409C>T p.S1470L | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV52505600, COSV99349892; called by muse, mutect2, varscan2
- KIAA1549L | c.4397T>C p.M1466T (on ENST00000321505; = p.M1763T on NM_012194.3) | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58591701; called by muse, mutect2, varscan2
- KNDC1 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs777749610; called by muse, mutect2, varscan2
- KRTAP23-1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 88/182 reads (48%) | PolyPhen benign (0.011); catalogued as rs750836659, COSV100492653; called by muse, varscan2
- NXNL1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 195/298 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs750452704; called by muse, mutect2, varscan2
- PIP5K1C | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1327057944; called by muse, mutect2, varscan2
- PRPF19 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99920808; called by muse, mutect2, varscan2
- RGS16 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as COSV62375743; called by muse, mutect2, varscan2
- SHISA7 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1254630975; called by muse, mutect2
- STXBP1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64814620; called by muse, mutect2, varscan2
- TMEM8B | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV65075671; called by muse, mutect2, varscan2
- TMF1 | c.2152-4A>G | Splice Region (SNP) | VAF 10/232 reads (4%) | catalogued as rs1464766108; called by muse, mutect2
- TSR3 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371158812; called by muse, mutect2, varscan2
- WDFY4 | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1335421324; called by muse, mutect2
- ABHD16A | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ACAN | c.5131T>A p.S1711T | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ADCY7 | c.3164A>G p.N1055S | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ALG13 | c.2629dup p.T877Nfs*72 | Frame Shift Ins (INS) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2338A>T p.S780C | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- C3orf80 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CABP7 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CATSPERE | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CBX5 | c.374del p.K125Rfs*12 | Frame Shift Del (DEL) | VAF 100/241 reads (41%) | called by mutect2, pindel, varscan2
- CD163L1 | c.746A>C p.D249A | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.717); called by muse, mutect2
- CLCNKA | c.1163G>A p.W388* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- COL9A3 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CPA5 | c.1185C>G p.S395R | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CRISPLD1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB14 | c.98_99del p.K33Sfs*27 | Frame Shift Del (DEL) | VAF 76/284 reads (27%) | called by mutect2, pindel, varscan2
- DOCK3 | c.4199T>G p.M1400R | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DUSP23 | c.151_156del p.D51_S52del | In Frame Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- EHMT2 | c.2743del p.A915Pfs*48 | Frame Shift Del (DEL) | VAF 67/210 reads (32%) | called by mutect2, pindel, varscan2
- ERBIN | c.3659G>T p.G1220V | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FAM20C | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FLG | c.1858A>T p.S620C | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD4 | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 54/54 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INSYN1 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 129/505 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INTS8 | c.306T>G p.S102R | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KCNN2 | c.47A>G p.N16S (on ENST00000264773; = p.N228S on NM_021614.4) | Missense Mutation (SNP) | VAF 88/293 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2B | c.4620T>G p.Y1540* | Nonsense Mutation (SNP) | VAF 23/313 reads (7%) | called by muse, mutect2
- KPNA5 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRP2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTB | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 159/242 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LTK | c.2068A>G p.M690V | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MCTP2 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12L | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGA | c.5120C>G p.S1707C | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MOB3A | c.493C>G p.H165D | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A1 | c.708dup p.E237Rfs*5 | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | called by mutect2, varscan2
- MTX1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOX3 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- OLFM4 | c.506T>A p.L169Q | Missense Mutation (SNP) | VAF 118/122 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OXR1 | c.1387G>C p.E463Q (on ENST00000442977 / NM_001198532.1; = p.E462Q on NM_018002.3) | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PGC | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PHF14 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PLA2G4E | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- PNP | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PSMC1 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RBCK1 | c.1138T>A p.C380S (on ENST00000356286 / NM_031229.4; = p.C338S on NM_006462.6) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RDH12 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RFPL3 | c.236G>C p.C79S (on ENST00000249007 / NM_001098535.1; = p.C50S on NM_006604.2) | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2
- RGS16 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- RXFP4 | c.195T>G p.S65R | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIT1 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC22A6 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); called by muse, mutect2
- SLC35B1 | c.323T>A p.I108N (on ENST00000649906; = p.I71N on NM_005827.4) | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- SMARCA1 | c.2817+1_2817+6del p.X939_splice | Splice Site (DEL) | VAF 100/103 reads (97%) | called by mutect2, pindel, varscan2
- TGDS | c.555+2T>A p.X185_splice | Splice Site (SNP) | VAF 34/36 reads (94%) | called by muse, mutect2, varscan2
- TSPEAR | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TTC7B | c.913_914del p.T305Sfs*30 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- UACA | c.1582A>C p.T528P | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2
- UBE2H | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- UBR4 | c.6729G>T p.M2243I | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ULK1 | c.857A>T p.K286I | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UNC13A | c.4457A>G p.E1486G | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- VN1R4 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VWC2 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWCE | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZFHX4 | c.5662C>A p.Q1888K | Missense Mutation (SNP) | VAF 143/353 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF208 | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF615 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF879 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BEND5 | c.483G>T p.V161= | Silent (SNP) | VAF 69/218 reads (32%) | called by muse, varscan2
- CACNA1C | c.5242C>T p.L1748= | Silent (SNP) | VAF 198/382 reads (52%) | called by muse, mutect2, varscan2
- CDH17 | c.183A>G p.E61= | Silent (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- HDHD3 | c.255G>T p.L85= | Silent (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- IGLV3-1 | c.195C>T p.V65= | Silent (SNP) | VAF 66/66 reads (100%) | called by muse, varscan2
- INHBC | c.510G>A p.L170= | Silent (SNP) | VAF 14/209 reads (7%) | catalogued as COSV59006302; called by muse, mutect2
- KLHL32 | c.1450A>C p.R484= | Silent (SNP) | VAF 157/264 reads (59%) | called by muse, mutect2, varscan2
- KLHL6 | c.39T>G p.G13= | Silent (SNP) | VAF 77/164 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.225A>G p.P75= | Silent (SNP) | VAF 146/233 reads (63%) | called by muse, varscan2
- NR2C1 | c.1149T>G p.P383= | Silent (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- OR2H1 | c.453G>T p.L151= | Silent (SNP) | VAF 79/253 reads (31%) | called by muse, mutect2, varscan2
- PHACTR3 | c.138C>A p.P46= | Silent (SNP) | VAF 90/198 reads (45%) | called by muse, mutect2, varscan2
- ROBO2 | c.2688G>A p.T896= | Silent (SNP) | VAF 59/79 reads (75%) | catalogued as rs754193459, COSV59897272; called by muse, mutect2, varscan2
- SALL4 | c.1536T>C p.S512= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- SARDH | c.2433G>A p.E811= | Silent (SNP) | VAF 86/248 reads (35%) | catalogued as rs1049985656; called by muse, mutect2, varscan2
- SCN10A | c.4302C>T p.F1434= | Silent (SNP) | VAF 64/195 reads (33%) | called by muse, mutect2, varscan2
- SETD3 | c.439C>A p.R147= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV59283634; called by muse, mutect2
- SIK2 | c.2781G>A p.*927= | Silent (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- SLC41A2 | c.1395T>C p.N465= | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2
- SPATA6 | c.993G>A p.K331= | Silent (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- TAPBPL | c.108C>A p.V36= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs779853136, COSV56948112; called by muse, mutect2, varscan2
- UNC5A | c.2416C>T p.L806= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- VSIR | c.402C>T p.R134= | Silent (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- WSCD1 | c.687C>T p.S229= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs779297258; called by muse, mutect2, varscan2
- ZNF407 | c.3606T>C p.N1202= | Silent (SNP) | VAF 102/207 reads (49%) | called by muse, mutect2, varscan2
- ABCC12 | c.*71G>A | 3'UTR (SNP) | VAF 100/212 reads (47%) | called by muse, mutect2, varscan2
- ABHD14B | c.*754G>A | 3'UTR (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- AC024651.2 | n.626A>C | RNA (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- ACAD11 | c.1414+57T>G | Intron (SNP) | VAF 76/211 reads (36%) | catalogued as COSV99391484; called by muse, mutect2, varscan2
- ADAM12 | c.*686G>C | 3'UTR (SNP) | VAF 85/170 reads (50%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.*1249G>A | 3'UTR (SNP) | VAF 36/147 reads (24%) | catalogued as rs550210288; called by muse, mutect2, varscan2
- ADAMTSL3 | c.*1299T>G | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826285 C>T | 5'Flank (SNP) | VAF 386/1157 reads (33%) | called by muse, mutect2, varscan2
- AOPEP | c.*5-685T>G | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*1764A>C | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*821T>A | 3'UTR (SNP) | VAF 24/106 reads (23%) | catalogued as COSV101122946; called by muse, mutect2, varscan2
- BMP6 | c.*197_*199del | 3'UTR (DEL) | VAF 30/92 reads (33%) | called by pindel, varscan2
- CACNA1I | c.*193G>A | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2
- CALHM5 | c.*5897C>A | 3'UTR (SNP) | VAF 62/161 reads (39%) | called by muse, mutect2, varscan2
- CAPN3 | c.1782+252A>C | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- CCDC144A | c.4098+148G>A | Intron (SNP) | VAF 46/201 reads (23%) | catalogued as rs999227642; called by muse, mutect2, varscan2
- CCND3 | c.711+37C>T | Intron (SNP) | VAF 35/104 reads (34%) | catalogued as rs1425793857; called by muse, mutect2, varscan2
- CD300LD | chr17:74593314 A>T | 5'Flank (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- CEP170 | c.*425A>C | 3'UTR (SNP) | VAF 119/401 reads (30%) | called by muse, mutect2, varscan2
- CEP290 | c.441+491T>A | Intron (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- CGAS | c.*1426T>A | 3'UTR (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- CLU | c.*321G>T | 3'UTR (SNP) | VAF 61/107 reads (57%) | catalogued as rs115801357; called by muse, mutect2, varscan2
- COL7A1 | c.*49C>G | 3'UTR (SNP) | VAF 93/295 reads (32%) | catalogued as COSV99866415; called by muse, mutect2, varscan2
- CYP8B1 | c.*318C>A | 3'UTR (SNP) | VAF 63/191 reads (33%) | catalogued as rs1427598951; called by muse, mutect2, varscan2
- DGKB | c.*3840G>T | 3'UTR (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- DPP4 | c.7-45G>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs766825404; called by muse, mutect2
- EBF2 | c.*559A>C | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- EPHA7 | c.*1740del | 3'UTR (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- EPN3 | c.-103C>T | 5'UTR (SNP) | VAF 76/246 reads (31%) | called by muse, mutect2, varscan2
- EREG | c.*2274C>T | 3'UTR (SNP) | VAF 22/37 reads (59%) | catalogued as rs1192719254; called by muse, mutect2, varscan2
- FBXO42 | c.*891A>C | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by mutect2, varscan2
- FCRL5 | c.*1140C>T | 3'UTR (SNP) | VAF 219/329 reads (67%) | called by muse, mutect2, varscan2
- FKBP5 | c.*1502T>A | 3'UTR (SNP) | VAF 56/179 reads (31%) | called by muse, mutect2, varscan2
- FSTL1 | c.*2345_*2346dup | 3'UTR (INS) | VAF 59/106 reads (56%) | called by mutect2, varscan2
- GABBR2 | c.*1846T>A | 3'UTR (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- GCSAM | c.-63A>G | 5'UTR (SNP) | VAF 312/476 reads (66%) | called by muse, varscan2
- GINS4 | c.-4G>C | 5'UTR (SNP) | VAF 100/214 reads (47%) | called by muse, mutect2, varscan2
- GIPC3 | chr19:3593510 C>T | 3'Flank (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- GNGT1 | c.97-255T>A | Intron (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- HNRNPLL | c.802+168G>C | Intron (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- IRAG1 | c.*1543G>C | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- ITGB6 | c.*1720C>T | 3'UTR (SNP) | VAF 101/102 reads (99%) | catalogued as rs570975251; called by muse, mutect2, varscan2
- KCND1 | c.*250C>T | 3'UTR (SNP) | VAF 39/40 reads (98%) | called by muse, mutect2, varscan2
- LARP6 | c.200+2277C>A | Intron (SNP) | VAF 236/702 reads (34%) | called by muse, mutect2, varscan2
- LEF1 | c.213+767G>T | Intron (SNP) | VAF 63/158 reads (40%) | catalogued as rs370815041; called by muse, mutect2, varscan2
- LILRB4 | c.758-9A>T | Intron (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- LINC00943 | n.1337G>C | RNA (SNP) | VAF 59/107 reads (55%) | called by muse, varscan2
- LIPA | c.*630_*633del | 3'UTR (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- LONRF2 | c.*1485A>G | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- LRRTM3 | c.-135C>A | 5'UTR (SNP) | VAF 127/332 reads (38%) | catalogued as COSV63662114; called by muse, mutect2, varscan2
- LTB | c.208+74A>T | Intron (SNP) | VAF 129/182 reads (71%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.*498G>A | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- MCM4 | c.*1290A>C | 3'UTR (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- MGAM | c.*276G>C | 3'UTR (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- MIR5195 | n.13G>C | RNA (SNP) | VAF 58/119 reads (49%) | catalogued as rs754800856; called by muse, varscan2
- MLH1 | chr3:36993420 C>A | 5'Flank (SNP) | VAF 66/230 reads (29%) | catalogued as rs1427901980; called by muse, mutect2, varscan2
- MMP15 | c.*413T>C | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- MR1 | c.*6432T>C | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- MS4A12 | c.*243T>A | 3'UTR (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- MUC4 | c.*258C>A | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- MYBL1 | c.*1061A>T | 3'UTR (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- MYDGF | c.369+45C>A | Intron (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- NAA25 | c.*461C>T | 3'UTR (SNP) | VAF 26/99 reads (26%) | catalogued as rs1232140485; called by muse, mutect2, varscan2
- NAMPTP1 | n.2278C>G | RNA (SNP) | VAF 7/186 reads (4%) | called by muse, mutect2
- NANOG | c.*999G>A | 3'UTR (SNP) | VAF 59/102 reads (58%) | called by muse, mutect2, varscan2
- NETO1 | c.-306C>T | 5'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- NEURL1B | c.*2664G>T | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- NFIB | c.*2519T>A | 3'UTR (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- NKX2-4 | c.*153C>T | 3'UTR (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- NPAS3 | chr14:33802861 C>A | 3'Flank (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- NRIP2 | c.*31G>A | 3'UTR (SNP) | VAF 18/240 reads (8%) | catalogued as COSV99957906; called by muse, mutect2
- NUP155 | c.*2370A>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- OR4C12 | c.*56G>T | 3'UTR (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- OR51E1 | c.*1022C>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- PDGFC | c.*2312dup | 3'UTR (INS) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- PDLIM3 | c.*271C>A | 3'UTR (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- PHF6 | c.*2879T>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- PLA2R1 | c.*297G>A | 3'UTR (SNP) | VAF 19/66 reads (29%) | catalogued as rs924649530, COSV51774762; called by muse, mutect2, varscan2
- PRKAG2 | c.466+44971del | Intron (DEL) | VAF 49/277 reads (18%) | called by mutect2, pindel, varscan2
- RAB40A | c.-70-1434G>A | Intron (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- RBM22 | c.-47C>T | 5'UTR (SNP) | VAF 65/298 reads (22%) | catalogued as rs918418017; called by muse, mutect2, varscan2
- RIN3 | c.2631+144A>C | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- RNF150 | c.*1633G>A | 3'UTR (SNP) | VAF 31/84 reads (37%) | catalogued as rs575394157; called by muse, mutect2, varscan2
- RNU6-354P | chr15:43736893 G>T | 5'Flank (SNP) | VAF 16/172 reads (9%) | catalogued as rs932514248; called by muse, mutect2, varscan2
- RPA1 | c.361+4983T>A | Intron (SNP) | VAF 83/189 reads (44%) | called by muse, mutect2, varscan2
- RSAD1 | c.*963C>A | 3'UTR (SNP) | VAF 47/173 reads (27%) | called by muse, mutect2
- RSPRY1 | c.*626T>C | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- RUNX2 | c.*2619dup | 3'UTR (INS) | VAF 66/124 reads (53%) | called by mutect2, pindel, varscan2
- SCN3B | c.*1665A>C | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- SCRN2 | c.773-19C>T | Intron (SNP) | VAF 92/260 reads (35%) | called by muse, mutect2, varscan2
- SEMA6D | c.*1980A>C | 3'UTR (SNP) | VAF 42/147 reads (29%) | called by muse, mutect2, varscan2
- SFT2D2 | c.*369C>T | 3'UTR (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- SLC1A4 | c.*2195T>C | 3'UTR (SNP) | VAF 43/44 reads (98%) | called by muse, mutect2, varscan2
- SLC39A5 | c.1479+77C>T | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1169983254; called by muse, mutect2, varscan2
- SMC4 | c.*713T>A | 3'UTR (SNP) | VAF 49/167 reads (29%) | called by muse, mutect2, varscan2
- SPATS2L | c.*232G>T | 3'UTR (SNP) | VAF 10/86 reads (12%) | catalogued as COSV62345358; called by muse, mutect2
- SPRN | c.*374G>A | 3'UTR (SNP) | VAF 73/142 reads (51%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*4300G>C | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- STAG3L4 | n.1989C>G | RNA (SNP) | VAF 76/556 reads (14%) | called by muse, mutect2
- SURF4 | c.*992C>T | 3'UTR (SNP) | VAF 106/301 reads (35%) | called by muse, mutect2, varscan2
- TBC1D21 | c.*21G>A | 3'UTR (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- TMEM235 | c.*61G>T | 3'UTR (SNP) | VAF 73/236 reads (31%) | called by muse, mutect2, varscan2
- TNS1 | c.*2032G>A | 3'UTR (SNP) | VAF 18/214 reads (8%) | catalogued as rs1287295047; called by muse, mutect2
- TPMT | c.*310dup | 3'UTR (INS) | VAF 15/49 reads (31%) | called by mutect2, varscan2
- TRIM7 | c.619-495A>C | Intron (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- TSPAN31 | c.-55C>A | 5'UTR (SNP) | VAF 91/218 reads (42%) | called by muse, mutect2, varscan2
- TTC3 | c.-150A>T | 5'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- WDR91 | c.*361G>A | 3'UTR (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- XPR1 | c.*1540G>C | 3'UTR (SNP) | VAF 94/247 reads (38%) | catalogued as rs1192537540; called by muse, mutect2, varscan2
- ZBTB40 | c.*10C>T | 3'UTR (SNP) | VAF 42/78 reads (54%) | catalogued as rs1164926240; called by muse, mutect2, varscan2
- ZCCHC9 | c.-3106T>C | 5'UTR (SNP) | VAF 74/266 reads (28%) | catalogued as rs948599780; called by muse, mutect2, varscan2
- ZNF20 | c.*192G>A | 3'UTR (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- ZNF713 | chr7:55942083 T>C | 3'Flank (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- ZNF782 | c.*1133T>A | 3'UTR (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
